TCGA case TCGA-B6-A401 — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/48ff0420-0f19-4e9d-a75d-6c54949a461a

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 47 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 47.7 years (17,438 days); Year of diagnosis: 2007; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T1c; AJCC pathologic N: N1a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Left Upper Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 4; Micrometastasis present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Docetaxel + Doxorubicin; Days to treatment start: 50 days; Days to treatment end: 155 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 205 days; Days to treatment end: 284 days; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Letrozole; Days to treatment start: 375 days (1.0 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.

Follow-up (2 entries)
- Days to follow up: 1,989 days (5.4 years); Disease response: Tumor Free.
- Days to follow up: 2,596 days (7.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Negative; Staining intensity value: 1+; Test value range: <10%.
- ESR1 (IHC): Positive; Staining intensity scale: 4 Point Scale; Staining intensity value: 2+; Test value range: 80-89%.
- PGR (IHC): Positive; Staining intensity scale: 4 Point Scale; Staining intensity value: 3+; Test value range: 90-99%.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B6-A401-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 30 mg.
  Slide TCGA-B6-A401-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 8; Percent necrosis: 0; Percent stromal cells: 2; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-B6-A401-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Axillary staging method: Sentinel lymph node biopsy plus axillary dissection; Surgical procedure first: Lumpectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Micromet detection by IHC: No; Er IHC score: 2+; Her2 IHC score: 1+; Method initial path diagnosis: Core needle biopsy; Her2 IHC percent positive: <10%; Prospective collection: No; Retrospective collection: Yes; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Upper Outer Quadrant.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Doxetaxel.
- Drug treatment 4: Pharmaceutical therapy drug name: Femara.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,596 days; disease-specific survival: no event (censored), 2,596 days; disease-free interval: no event (censored), 2,596 days; progression-free interval: no event (censored), 2,596 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B6-A401-01A-11D-A238-01): tumor purity 0.3, ploidy 3.43, whole-genome doublings 2.
